Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4712, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4712-01A (Primary Tumor).

FINAL DIAGNOSIS:

KIDNEY, LEFT, NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE (See synoptic).
- B. FUHRMAN NUCLEAR GRADE IS 3 OF 4.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 8.5 cm.
- D. THE TUMOR INVOLVES RENAL SINUS FAT (SLIDE F).
- E. NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- F. ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- G. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- H. THE NON-NEOPLASTIC KIDNEY SHOWS FOCAL GLOBAL GLOMERULOSCLEROSIS; MARKED TUBULAR ATROPHY WITH KIDNEY "THYROIDIZATION", INTERSTITIAL FIBROSIS AND CHRONIC INFLAMMATION.
- I. TNM STAGE: pT3a NX MX.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY KIDNEY TUMORS

SPECIMEN TYPE:	Other: Nephrectomy
LATERALITY:	Left
TUMOR SITE:	Lower pole
FOCALITY:	Multifocal
TUMOR SIZE:	Greatest dimension: 8.5 cm Additional dimensions: 8.2 x 5.5 cm
MACROSCOPIC EXTENT OF TUMOR:	Tumor extension into perinephric tissues
HISTOLOGIC TYPE:	Clear cell (conventional) renal carcinoma
HISTOLOGIC GRADE (Fuhrman Nuclear Grade):	G3
PATHOLOGIC STAGING (pTNM):	pT3a pNX Number of regional lymph nodes examined: 0 pMX
MARGINS:	Margins uninvolved by invasive carcinoma
ADRENAL GLAND:	Not present
VENOUS (LARGE VESSEL) INVASION (V):	Absent
LYMPHATIC (SMALL VESSEL) INVASION (L):	Present
ADDITIONAL PATHOLOGIC FINDINGS:	Other: glomerulosclerosis and thyroidization

Source: NCI Genomic Data Commons file c0468191-6aca-43ee-81dd-cd5871a15aca (TCGA-B0-4712.01D92A98-9F18-44BF-83B6-CCC968D25C21.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).